Somatic mutation profile of tumor specimen TCGA-61-1733-01A (aliquot TCGA-61-1733-01A-01W-0639-09) from TCGA case TCGA-61-1733, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.7 years (26,180 days).
Specimen TCGA-61-1733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 218923d5-15f9-467b-a1e7-378ab0e77b2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1733-11A (Solid Tissue Normal), aliquot TCGA-61-1733-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/256749a1-d477-4954-a75c-f83d97e08c52

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 16, Nonsense Mutation 5, RNA 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT1 | c.247dup p.R83Pfs*106 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | catalogued as rs1554601559; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ASXL3 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as rs753638332, COSV52482746; called by muse, mutect2, varscan2
- BMS1 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 110/382 reads (29%) | catalogued as COSV65735824; called by muse, mutect2, varscan2
- C1D | c.331A>T p.R111* | Nonsense Mutation (SNP) | VAF 41/177 reads (23%) | catalogued as COSV63413985; called by muse, mutect2, varscan2
- CEL | c.2245C>A p.Q749K (on ENST00000673714; = p.Q746K on NM_001807.6) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60830154; called by muse, mutect2, varscan2
- CLRN1 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 59/426 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.991); catalogued as COSV55807208; called by muse, mutect2, varscan2
- COL4A3 | c.3518G>A p.G1173D | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257719; called by muse, mutect2
- DLC1 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52300440; called by muse, mutect2
- DNAH9 | c.7346C>T p.A2449V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs756091405, COSV52371199, COSV52381800; called by mutect2, varscan2
- EEF1AKMT3 | c.577C>A p.Q193K | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as COSV100103458; called by muse, mutect2
- FBN1 | c.8519A>G p.K2840R | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57333180; called by muse, mutect2, varscan2
- FLG | c.2981G>A p.G994D | Missense Mutation (SNP) | VAF 83/377 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs150406394; called by muse, mutect2, varscan2
- GLT8D2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs143994495, COSV62562197; called by muse, mutect2, varscan2
- GRID2 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757620916, COSV56185450, COSV56283061; called by muse, mutect2, varscan2
- GYS2 | c.1656C>G p.I552M | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53921019, COSV53930228; called by muse, mutect2, varscan2
- H4C7 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV55101211; called by muse, mutect2, varscan2
- HERPUD2 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV60946710; called by muse, mutect2, varscan2
- HOXD10 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV50907226; called by muse, mutect2, varscan2
- IQGAP3 | c.4889G>C p.R1630P | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV63255255, COSV63255308; called by muse, mutect2, varscan2
- KCNAB2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1295637312, COSV51236943, COSV51240103; called by muse, mutect2, varscan2
- KRT36 | c.543-2A>T p.X181_splice | Splice Site (SNP) | VAF 20/59 reads (34%) | catalogued as COSV60204984; called by muse, mutect2, varscan2
- LAX1 | c.907A>G p.S303G | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV65850332; called by muse, mutect2, varscan2
- LEPR | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1433955773, COSV60758343, COSV60762153; called by muse, mutect2, varscan2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 57/238 reads (24%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- MTO1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369718258, COSV64774347; called by muse, mutect2, varscan2
- OR2L3 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 345/818 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100741880, COSV63456619; called by muse, mutect2, varscan2
- PCDHGA4 | c.1799C>A p.T600N | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs768015584, COSV54053218; called by muse, mutect2, varscan2
- RCHY1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377417374; called by muse, mutect2, varscan2
- RNF165 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV53978911; called by muse, mutect2, varscan2
- RPL22 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52379675; called by muse, mutect2, varscan2
- RTN2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); catalogued as COSV55594540; called by muse, mutect2
- SLC66A1 | c.68G>A p.W23* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV64321483; called by muse, mutect2, varscan2
- SRCAP | c.5633C>G p.P1878R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs747709839, COSV52669729, COSV52682773; called by muse, mutect2, varscan2
- SV2C | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs776492250, COSV59231225; called by muse, mutect2, varscan2
- TG | c.4681G>A p.E1561K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs934177345, COSV55097707; called by muse, mutect2, varscan2
- TLR10 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100457388, COSV104395281; called by muse, mutect2
- TMEM132B | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV54774045; called by muse, mutect2, varscan2
- TP53 | c.913A>T p.K305* | Nonsense Mutation (SNP) | VAF 111/135 reads (82%) | catalogued as COSV52688866, COSV52766207; called by muse, mutect2, varscan2
- TTN | c.16201A>G p.S5401G (on ENST00000591111; = p.S4474G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/283 reads (13%) | PolyPhen benign (0.037); catalogued as COSV60409970; called by muse, mutect2, varscan2
- TTN | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | PolyPhen benign (0.246); catalogued as COSV60409976; called by muse, mutect2, varscan2
- WSCD1 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58499099; called by muse, mutect2, varscan2
- ZNF608 | c.3834G>C p.E1278D | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV60442143; called by muse, mutect2, varscan2
- IGHV3-74 | c.344G>C p.C115S | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACTL7A | c.141G>A p.T47= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781438053, COSV61776914; called by muse, mutect2, varscan2
- DUSP16 | c.1674T>C p.Y558= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV53810287; called by muse, mutect2, varscan2
- FAM126A | c.1398G>A p.P466= | Silent (SNP) | VAF 50/195 reads (26%) | catalogued as rs752544627, COSV69471164; called by muse, mutect2, varscan2
- GFRA3 | c.261G>A p.L87= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV51232510; called by muse, mutect2, varscan2
- H2BC4 | c.357C>T p.V119= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs773685186, COSV58417829; called by muse, mutect2, varscan2
- JHY | c.489C>T p.L163= | Silent (SNP) | VAF 72/156 reads (46%) | catalogued as rs1465865829, COSV56222308; called by muse, mutect2, varscan2
- KIF18B | c.2469C>T p.P823= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100192215, COSV59276935; called by muse, mutect2, varscan2
- METTL14 | c.510A>G p.L170= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV66311487; called by muse, mutect2, varscan2
- MUC17 | c.9195C>G p.T3065= | Silent (SNP) | VAF 68/291 reads (23%) | catalogued as COSV60281526, COSV60307153; called by muse, mutect2, varscan2
- NTRK2 | c.1065C>T p.N355= | Silent (SNP) | VAF 55/154 reads (36%) | catalogued as COSV52886785; called by muse, mutect2, varscan2
- OAS2 | c.1356C>G p.V452= | Silent (SNP) | VAF 100/230 reads (43%) | catalogued as COSV100660032, COSV60804855; called by muse, mutect2, varscan2
- PHEX | c.159C>T p.Y53= | Silent (SNP) | VAF 10/157 reads (6%) | catalogued as COSV101039369; called by muse, mutect2
- PLA2R1 | c.720C>T p.H240= | Silent (SNP) | VAF 42/375 reads (11%) | catalogued as COSV51788426; called by muse, mutect2, varscan2
- RBBP6 | c.4182C>T p.N1394= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as COSV60509160; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1092T>G p.L364= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as COSV60159270; called by muse, mutect2, varscan2
- ZNF816 | c.504C>T p.H168= | Silent (SNP) | VAF 116/290 reads (40%) | catalogued as COSV54413042; called by muse, mutect2, varscan2
- LINC02145 | n.430C>T | RNA (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
